Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFB, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAFB-01A (Primary Tumor).

Department of Pathology

TCO-03
Seminoma NOS 906113
Site of Testis NOS 162.9
W 2/3/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 6.5 cm; tumor confined to testis in available slides;
angio-invasion present; invasion in rete testis present.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 7cefba33-0dd3-48e2-b000-67c90843a35e (TCGA-2G-AAFB-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).